Surgical pathology report (de-identified scan), TCGA case TCGA-4A-A93X, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mary Bird Perkins Cancer Center - Our Lady of the Lake, specimen TCGA-4A-A93X-01A (Primary Tumor).

[page 1 of 3]
ABNORMAL
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]	Result ID: [REDACTED]	Accession: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] Sex: M	Account: [REDACTED]	Date Collected: [REDACTED]
MRN: [REDACTED]	Patient: [REDACTED]	Date Received: [REDACTED]
Requested by: [REDACTED]		Date Reported: [REDACTED]
Copy to: [REDACTED]		

Clinical Data: Right kidney mass, biliary colic

FINAL PATHOLOGIC DIAGNOSIS

1. Right kidney, radical nephrectomy: Papillary renal cell carcinoma, see Synoptic Report.

2. Lymph nodes, pericaval, lymph node dissection:
Two lymph nodes positive for metastatic papillary renal cell carcinoma (2/2).
Largest metastatic deposit measures 2.2 cm in greatest dimension.
Extracapsular extension: Present.
See Comment.

Comment: Tumor extends to the inked surgical margin of the largest involved lymph node.

3. Gallbladder, cholecystectomy:
Chronic calculous cholecystitis.
Negative for malignancy.

ICD-C-3
Carcinoma, papillary renal cell 8260/3
Site @ Kidney NOS C64.9
JW 3/26/14

SYNOPTIC REPORT

Procedure:	Radical nephrectomy
Specimen laterality:	Right
Tumor site:	Superior pole
Tumor size:	8.5 cm in greatest dimension
Tumor focality:	Unifocal
Macroscopic extent of tumor:	Tumor extends into perinephric fat and into renal vein, renal artery, and ureter within the renal pelvis
Histologic type:	Papillary renal cell carcinoma
Sarcomatoid features:	Not identified
Tumor necrosis:	Present
Histologic grade:	Fuhrman nuclear grade G3
Microscopic tumor extension:	Tumor extends into the perinephric fat beyond the renal capsule, into the renal pelvis, renal vein, renal artery, and pelvic portion of ureter

[page 2 of 3]
SURGICAL PATHOLOGY REPORT - CONTINUED

Patient: [REDACTED]

Result ID [REDACTED]

Accession: [REDACTED]

Margins:

Renal parenchymal margin:
Perinephric fat margin:
Gerota's fascial margin:
Renal vein margin:
Renal artery margin:
Ureteral margin

Margins of main specimen uninvolved by invasive carcinoma (*see Comment*).

Negative
Negative
Negative
Negative
Negative
Negative

Lymphovascular invasion:

Present

Additional findings:

Adrenal gland: Uninvolved

Pathologic Tumor Stage:

pT3a pN1

Comment: While the margins of the main specimen are uninvolved, tumor is seen at the inked surgical margins surrounding the larger of the pericaval lymph nodes (specimen #2). The tumor is composed of papillary structures with fibrovascular cores, which are lined by tumor cells with amphophilic cytoplasm and large, slightly irregular nuclei with prominent eosinophilic nucleoli.

Pathologist, Electronic Signature

Intradepartmental consultation:

SPECIMEN(S) SUBMITTED: GROSS DESCRIPTION

- Right kidney mass:** In formalin labeled "right kidney mass" is a 15 x 7.5 x 6.5 cm kidney with abundant attached perinephric fat weight 1,721 grams in aggregate. There is 3.5 cm ureter extending from the renal hilum. The kidney is bivalved to reveal an ill defined 8.5 cm in greatest dimension variegated tan-white to red nodular tumor within the superior pole. On cut section, the tumor grossly appears to possibly extend into the perinephric fat at the superior pole. The lining of the renal pelvis is grey-white and slightly bosselated. Upon sectioning it appears that the tumor elevates the urothelium and it is unclear at gross dissection whether the tumor penetrates through the urothelium into the renal pelvis. The tumor also grossly extends into the renal artery, lying 5mm from the renal artery resection margin. The remaining renal parenchyma is pale tan-pink with an ill defined corticomedullary junction. There is a small portion of adrenal gland at the most superior aspect of the specimen with an orange red cut surface. The gland grossly does not appear to be involved by tumor. The perinephric fat is inked black. Representative sections are submitted in eight cassettes as labeled: A vascular and ureter margins, B tumor to include perinephric fat, C-D tumor to include renal pelvis, E tumor to include renal artery, F tumor to include uninvolved renal parenchyma, G normal renal parenchyma, H adrenal gland.
- Peri-caval node:** In formalin labeled "peri-caval node" are two nodular tan-pink tissues which measure 3.5 x 3 x 2.3 cm and 2.5 x 1.5 x 0.8 cm. The larger tissue is inked blue and the smaller tissue is inked black. Sectioning of the larger tissue reveals a slightly friable and partially cystic tan-pink cut surface containing coagulated blood. Sectioning of the smaller tissue reveals a partially cystic red-brown cut surface containing coagulated blood. Representative sections are submitted in 4 cassettes as follows: A-B entire smaller tissue, C-D larger tissue.
- Gallbladder:** In formalin labeled "gallbladder" is a 9.5 x 5 x 2.8 cm intact gallbladder. The serosa is tan-pink and dull. The cystic duct is 0.3 cm in diameter and patent. The gallbladder wall averages 0.2 cm in thickness. The mucosa is velvety yellow-red with diffuse yellow stippling within the body. The lumen contains tan-yellow viscous bile and a 2.5 cm green-black granular cholelith. Representative sections to include the cystic duct margin (inked black) are submitted in one cassette.

CPT CODE(S):

ICD-9 CODE(S):

FACILITY:

[page 3 of 3]
SURGICAL PATHOLOGY REPORT - CONTINUED

Patient: [REDACTED]	Result ID: [REDACTED]	Accession: [REDACTED]
---------------------	-----------------------	-----------------------

88307 x2, 88304

1840

END OF REPORT

Criteria hw 12/13/13	Yes	No

Source: NCI Genomic Data Commons file 441f9ca8-9b59-45b0-8feb-1ec67aabb785 (TCGA-4A-A93X.ED6B8969-93D9-4198-BE44-1538CE556F60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).